Somatic mutation profile of tumor specimen MP2PRT-PAVAYG-TMP1-A (aliquot MP2PRT-PAVAYG-TMP1-A-1-0-D-A80L-36) from MP2PRT case MP2PRT-PAVAYG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.7 years (613 days).
Specimen MP2PRT-PAVAYG-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 660b532d-b539-4a42-8fda-86b2f48337a1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVAYG-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVAYG-NB1-A-1-0-D-A80L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0b1a8f36-0bc2-4e9e-8de4-ec414aa17dc2

The open-access MAF lists 10 somatic variants for this specimen: 6 protein-altering or splice-affecting, 4 silent.
By variant classification: Silent 4, Missense Mutation 4, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ESR2 | c.754G>A p.A252T | Missense Mutation (SNP) | VAF 195/500 reads (39%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs543025691, COSV50831190; called by muse, mutect2, varscan2
- CCND3 | c.811dup p.R271Pfs*53 | Frame Shift Ins (INS) | VAF 63/524 reads (12%) | called by mutect2, pindel, varscan2
- ITGA7 | c.1309C>T p.Q437* (on ENST00000555728; = p.Q393* on NM_002206.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 105/268 reads (39%) | called by muse, mutect2, varscan2
- NBAS | c.6295G>T p.D2099Y | Missense Mutation (SNP) | VAF 50/290 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); called by mutect2, varscan2
- NWD2 | c.5131T>C p.S1711P | Missense Mutation (SNP) | VAF 123/314 reads (39%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- OPLAH | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 16/432 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HERC1 | c.6999G>A p.T2333= | Silent (SNP) | VAF 50/269 reads (19%) | catalogued as rs1162444461; called by muse, mutect2, varscan2
- KCNAB1 | c.264C>T p.G88= | Silent (SNP) | VAF 14/247 reads (6%) | called by muse, mutect2
- LRP6 | c.1929A>G p.R643= | Silent (SNP) | VAF 16/222 reads (7%) | called by muse, mutect2
- OR2G6 | c.36T>C p.F12= | Silent (SNP) | VAF 78/216 reads (36%) | called by muse, mutect2, varscan2
